EXCEPTIONAL_RESPONDERS case ER-B0BV — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d274d9f0-d65b-4bfa-90eb-e15879be295a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1948; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: metastasis; Age at diagnosis: 62.6 years (22,862 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC clinical stage: Stage IIIA; Prior malignancy: no; Days to last follow up: 2,442 days (6.7 years); Days to best overall response: 0 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Capecitabine + Oxaliplatin; Days to treatment start: 635 days (1.7 years); Days to treatment end: 811 days (2.2 years).

Follow-up (1 entry)
- Days to follow up: 2,442 days (6.7 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 616 days (1.7 years); Days progression-free: 2,442 days (6.7 years).

Biospecimens (3 samples)
- Sample ER-B0BV-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample ER-B0BV-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample ER-B0BV-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
